Somatic mutation profile of tumor specimen 0E1NZT from CCDI case PBCVUM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1NZT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60f35444-f639-429e-9947-daa32eb966b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a80c91c0-a003-4466-b5d0-d5e38915c6ab

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MST1R | c.3991C>T p.R1331* | Nonsense Mutation (SNP) | VAF 38/143 reads (27%) | catalogued as rs1397526390; called by muse, mutect2, varscan2
- ZFP36L1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 101/383 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs763117294; called by muse, mutect2, varscan2
- PANK3 | c.482A>C p.Y161S | Missense Mutation (SNP) | VAF 64/450 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PTPRB | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DGKZ | c.-55del | 5'UTR (DEL) | VAF 8/48 reads (17%) | catalogued as rs554550354; called by mutect2, varscan2
- TOR1A | c.748+53A>T | Intron (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
